Gene-level copy-number profile of tumor specimen TCGA-QQ-A5V9-01A from TCGA case TCGA-QQ-A5V9, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 76.6 years (27,977 days).
Specimen TCGA-QQ-A5V9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a6fa13c1-e24c-4f28-9e87-3bb24e6a2fde.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QQ-A5V9-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/463fa5d4-df2e-464c-b1ea-518c924d459c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 348; copy number 2: 11,764; copy number 3: 24,470; copy number 4: 12,791; copy number 5: 3,635; copy number 6: 3,228; copy number 7: 795; copy number 8: 625; copy number 9: 648; copy number 10: 1,352; copy number 11: 11; copy number 14: 30; copy number 15: 2; copy number 16: 3; copy number 17: 25; copy number 24: 26; copy number 26: 41; copy number 46: 8; copy number 48: 6; copy number 72: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QQ-A5V9-01A-11D-A32H-01): tumor purity 0.48, ploidy 3.52, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,544 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:81,986,138–82,808,021, 3 genes, copy number 7: LINC02008, RPL7AP23, CYP51A1P1.
- chr3:85,799,987–91,513,775, 43 genes, copy number 10–72: CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr5:58,198–997,308, 38 genes, copy number 9: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1.
- chr5:12,794,100–45,895,970, 465 genes, copy number 8–11 (broad region; genes not listed).
- chr5:75,910,283–76,377,149, 14 genes, copy number 7: AC108120.2, BIN2P2, AC108120.1, SAP18P1, AC026774.2, AC026774.1, SV2C, RNA5SP186, AC113404.2, AC113404.3, HMGN2P4, PDCD5P2, AC113404.1, SNRPCP2.
- chr5:76,510,440–76,510,766, 1 gene, copy number 7: AC112173.1.
- chr6:51,615,299–54,945,099, 78 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr6:65,788,417–66,094,909, 3 genes, copy number 8: SLC25A51P1, ADH5P4, NUFIP1P1.
- chr6:68,598,204–69,389,506, 3 genes, copy number 16 (within-gene range 3–16): AL606923.1, AL391807.1, ADGRB3.
- chr7:70,972–62,275,678, 1,079 genes, copy number 9–10 (broad region; genes not listed).
- chr7:92,540,268–94,011,113, 27 genes, copy number 15–17 (within-gene range 3–17): AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1.
- chr8:138,588,235–145,066,685, 214 genes, copy number 7 (broad region; genes not listed).
- chr9:30,388,935–32,573,184, 23 genes, copy number 7: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1.
- chr9:103,999,755–105,552,433, 27 genes, copy number 7 (within-gene range 5–7): AL590381.1, SMC2-AS1, SMC2, TOPORSLP, AL512646.1, OR13F1, AL450426.1, OR13C4, OR13C3, OR13C8, OR13D2P, OR13C5, OR13C2, OR13C9, OR13I1P, OR13C1P, OR13D1, OR13D3P, NIPSNAP3A, NIPSNAP3B, ABCA1, AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1, FSD1L.
- chr9:115,888,169–117,466,260, 16 genes, copy number 7: LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1.
- chr18:1,509,022–8,406,861, 112 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr18:8,688,022–12,129,764, 100 genes, copy number 7 (broad region; genes not listed).
- chr20:28,563,850–61,083,750, 774 genes, copy number 7–10 (broad region; genes not listed).
- chr20:61,267,525–61,437,630, 3 genes, copy number 7: AL365229.1, BX640515.1, AL160412.1.
- chr21:24,154,871–25,057,746, 6 genes, copy number 9 (within-gene range 6–9): AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1.
- chr21:26,349,780–29,073,797, 35 genes, copy number 9–24: AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3.
- chr21:29,536,933–29,940,033, 1 gene, copy number 26 (within-gene range 6–26): GRIK1.
- chr21:29,748,175–46,665,124, 479 genes, copy number 7–26 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 348. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
